Somatic mutation profile of tumor specimen TCGA-EM-A3O7-01A (aliquot TCGA-EM-A3O7-01A-11D-A21Z-08) from TCGA case TCGA-EM-A3O7, project TCGA-THCA (Thyroid Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Thyroid gland; AJCC pathologic stage: Stage III; Age at diagnosis: 46.1 years (16,842 days).
Specimen TCGA-EM-A3O7-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2127b999-9014-492b-b206-1122dae53374.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EM-A3O7-10A (Blood Derived Normal), aliquot TCGA-EM-A3O7-10A-01D-A21Z-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1e49cb4d-ceac-4870-85ac-75220833a36c

The open-access MAF lists 13 somatic variants for this specimen: 9 protein-altering or splice-affecting, 4 silent.
By variant classification: Missense Mutation 7, Silent 4, Frame Shift Del 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 61/140 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- MYH1 | c.3013G>A p.E1005K | Missense Mutation (SNP) | VAF 15/193 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.902); catalogued as COSV56844852; called by muse, mutect2
- PDZRN4 | c.2516G>T p.R839I (on ENST00000402685 / NM_001164595.2; = p.R581I on NM_013377.4) | Missense Mutation (SNP) | VAF 14/223 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.302); catalogued as COSV54201063; called by muse, mutect2
- POGZ | c.3781A>T p.I1261F | Missense Mutation (SNP) | VAF 10/240 reads (4%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.757); catalogued as COSV51851428; called by muse, mutect2
- SLC39A7 | c.506T>A p.L169H | Missense Mutation (SNP) | VAF 76/148 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV63399711; called by muse, mutect2, varscan2
- VNN2 | c.1436T>C p.L479P | Missense Mutation (SNP) | VAF 55/113 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58472486; called by muse, mutect2, varscan2
- ZNF563 | c.506A>G p.Y169C | Missense Mutation (SNP) | VAF 49/138 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.955); catalogued as rs774904148, COSV53370575; called by muse, mutect2, varscan2
- COG8 | c.1438del p.H480Ifs*31 | Frame Shift Del (DEL) | VAF 20/63 reads (32%) | called by mutect2, pindel, varscan2
- RBBP8NL | c.595_607del p.A199Sfs*7 | Frame Shift Del (DEL) | VAF 33/115 reads (29%) | called by mutect2, pindel, varscan2
- COL1A1 | c.1600C>T p.L534= | Silent (SNP) | VAF 48/93 reads (52%) | catalogued as COSV56804814; called by muse, mutect2, varscan2
- TAS2R20 | c.816A>G p.P272= | Silent (SNP) | VAF 9/115 reads (8%) | catalogued as rs1211571312, COSV67855779; called by muse, mutect2
- TMEM132A | c.375C>G p.A125= | Silent (SNP) | VAF 14/165 reads (8%) | catalogued as COSV50005658; called by muse, mutect2
- WIPF1 | c.456G>A p.V152= | Silent (SNP) | VAF 7/53 reads (13%) | catalogued as COSV55814439; called by muse, mutect2, varscan2
